Somatic mutation profile of tumor specimen TARGET-10-PARIIA-09A (aliquot TARGET-10-PARIIA-09A-01D) from TARGET case TARGET-10-PARIIA, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 13.1 years (4,801 days).
Specimen TARGET-10-PARIIA-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a698e4d3-04ec-4f41-8e9e-0d7359f8fc14.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARIIA-10A (Blood Derived Normal), aliquot TARGET-10-PARIIA-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/35a8694f-d38d-45a8-a3e0-37735f32050b

The open-access MAF lists 16 somatic variants for this specimen: 11 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 3, Intron 2, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DRC3 | c.1336G>A p.D446N | Missense Mutation (SNP) | VAF 44/87 reads (51%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.737); catalogued as rs571427963; called by muse, mutect2, varscan2
- EPHA7 | c.1342G>A p.G448R | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.46); PolyPhen benign (0.079); catalogued as rs769773179; called by muse, mutect2, varscan2
- LRP2 | c.12493C>T p.R4165C | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs570499038, COSV55543051; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NRSN1 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs769474942, COSV65894204; called by muse, mutect2, varscan2
- ZFP36L2 | c.533A>G p.H178R | Missense Mutation (SNP) | VAF 52/120 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56697683; called by muse, mutect2, varscan2
- AC093155.3 | c.371+1G>A p.X124_splice | Splice Site (SNP) | VAF 18/37 reads (49%) | called by muse, mutect2, varscan2
- BICC1 | c.1598C>A p.S533Y | Missense Mutation (SNP) | VAF 23/38 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- EYA1 | c.1442T>C p.L481P | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- HDHD5 | c.661G>T p.G221C (on ENST00000336737 / NM_033070.3; = p.G191C on NM_017829.5) | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- KMT2D | c.13636_13637del p.R4546Gfs*28 | Frame Shift Del (DEL) | VAF 10/80 reads (13%) | called by mutect2, pindel, varscan2
- ZFP36L2 | c.642C>A p.F214L | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- CSMD2 | c.6588G>A p.P2196= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as rs754541648; called by muse, mutect2, varscan2
- GRIP1 | c.363G>A p.L121= | Silent (SNP) | VAF 32/69 reads (46%) | called by muse, mutect2, varscan2
- ZSWIM3 | c.1749G>A p.R583= | Silent (SNP) | VAF 10/109 reads (9%) | called by muse, mutect2, varscan2
- AL359922.1 | c.348-35103A>T | Intron (SNP) | VAF 47/97 reads (48%) | catalogued as COSV64270776; called by muse, mutect2, varscan2
- P2RX5 | c.534-31C>T | Intron (SNP) | VAF 23/49 reads (47%) | called by muse, mutect2, varscan2
